Gene-level copy-number profile of tumor specimen ALCH-B1TL-TTR1-A from ALCHEMIST case ALCH-B1TL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 65.1 years (23,771 days).
Specimen ALCH-B1TL-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d74d4405-8595-4608-81db-83b0078ae129.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1TL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,749 have no estimate.
https://portal.gdc.cancer.gov/files/42501186-bc43-4d1d-b0b5-299e30c1d731

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 427; copy number 1: 17,535; copy number 2: 32,471; copy number 3: 5,721; copy number 4: 2,701; copy number 5: 12; copy number 8: 4; copy number 23: 3.

Homozygous deletions (total copy number 0; autosomes only): 140 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,784,376–143,797,108, 3 genes: AC239800.3, LINC02591, RNU1-143P.
- chr1:143,905,487–143,934,776, 2 genes: AC246680.1, RPL22P5.
- chr9:13,274,510–13,279,187, 1 gene (within-gene range 0–1): AL162386.2.
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–1): MIR31HG.
- chr9:21,480,839–22,214,672, 21 genes (within-gene range 0–1): IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:60,914,407–63,143,401, 63 genes (broad region; genes not listed).
- chr10:46,233,885–46,382,626, 5 genes (within-gene range 0–1): ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1.
- chr10:46,415,853–46,416,413, 1 gene (within-gene range 0–1): HNRNPA1P33.
- chr14:44,290,997–44,480,626, 3 genes (within-gene range 0–1): YWHAZP1, AL161752.1, LINC02277.
- chr16:32,475,051–32,478,250, 1 gene: ABCD1P3.
- chr17:18,415,728–18,661,950, 20 genes (within-gene range 0–1): KRT17P5, YWHAEP2, KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2, CCDC144B, AC107983.1, Metazoa_SRP, TBC1D28, AC026271.2, AC026271.4, AC026271.1.
- chr19:24,162,370–24,163,425, 1 gene: AC073534.1.
- chr21:8,603,547–9,368,775, 18 genes: RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,527,724–12,528,420, 1 gene, copy number 5: LINC02766.
- chr8:40,298,697–41,032,998, 6 genes, copy number 5–8: SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P.
- chr8:125,430,358–125,541,373, 2 genes, copy number 5: TRIB1, AC091114.1.
- chr9:111,896,814–111,935,369, 2 genes, copy number 5: UGCG, MIR4668.
- chr15:34,978,341–35,011,191, 5 genes, copy number 5: ZNF770, AC114546.3, AC114546.1, AC114546.4, AC114546.2.
- chr17:38,181,659–38,257,192, 3 genes, copy number 23: TBC1D3, NPEPPSP1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 14,973. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
